Somatic mutation profile of tumor specimen C3L-01925-07 (aliquot CPT0113690009) from CPTAC case C3L-01925, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IV; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 65.4 years (23,870 days).
Specimen C3L-01925-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ded9a424-a11d-4a10-9d10-e02c50f984b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01925-31 (Blood Derived Normal), aliquot CPT0114410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29137404-8f00-4817-9545-e5798140fd57

The open-access MAF lists 50 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 11, Frame Shift Del 3, 5'UTR 2, Intron 2, Nonsense Mutation 1, Splice Region 1, 5'Flank 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 96/247 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRD2 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.594); catalogued as rs778718767, COSV58341383; called by muse, mutect2, varscan2
- ANKRD13C | c.673T>C p.F225L | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52029794; called by muse, mutect2, varscan2
- EIF2D | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 101/248 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs543704357; called by muse, mutect2, varscan2
- ENPP6 | c.1250G>C p.R417P | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs28756320; called by muse, mutect2
- FBN3 | c.8051G>A p.R2684Q | Missense Mutation (SNP) | VAF 68/108 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs745699186, COSV54476332; called by muse, mutect2, varscan2
- ITPRID2 | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs112676123; called by muse, mutect2
- LHX3 | c.199G>A p.E67K (on ENST00000371748 / NM_178138.6; = p.E72K on NM_014564.5) | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs773397412, COSV100871291; called by muse, mutect2, varscan2
- SFMBT2 | c.1052C>A p.A351E | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs1164281001, COSV100739597; called by muse, mutect2, varscan2
- SIRT7 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 138/202 reads (68%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); catalogued as rs1348487595; called by muse, mutect2, varscan2
- SLC25A47 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 153/688 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs374474564; called by muse, varscan2
- TP53 | c.1028del p.E343Gfs*2 | Frame Shift Del (DEL) | VAF 200/347 reads (58%) | catalogued as COSV52822268, COSV99436358; called by mutect2, pindel, varscan2
- ACIN1 | c.2654A>C p.E885A | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- B4GALNT3 | c.445del p.H149Ifs*6 | Frame Shift Del (DEL) | VAF 39/176 reads (22%) | called by mutect2, pindel, varscan2
- CASP5 | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CRACR2A | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCC | c.1267C>A p.P423T | Missense Mutation (SNP) | VAF 76/412 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- DGKK | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- DMD | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EML6 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- FCGBP | c.6338C>T p.T2113I | Missense Mutation (SNP) | VAF 42/447 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- GCN1 | c.729+3G>C | Splice Region (SNP) | VAF 60/317 reads (19%) | called by muse, mutect2, varscan2
- HMCN2 | c.14849G>T p.R4950L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2
- INPPL1 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 50/275 reads (18%) | called by muse, mutect2, varscan2
- KIF21B | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 120/244 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- MED12 | c.3572A>G p.D1191G | Missense Mutation (SNP) | VAF 152/480 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MICALL2 | c.950G>T p.R317M | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- MRPL40 | c.503del p.L168Rfs*47 | Frame Shift Del (DEL) | VAF 106/407 reads (26%) | called by mutect2, pindel, varscan2
- MYO10 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 83/363 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBPF12 | c.228G>C p.Q76H | Missense Mutation (SNP) | VAF 180/557 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- PCDHA1 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 145/478 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- SLC12A6 | c.1732T>A p.F578I (on ENST00000354181 / NM_001365088.1; = p.F527I on NM_005135.2) | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CCNB1 | c.1176A>G p.Q392= | Silent (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- DCST2 | c.1590C>G p.S530= | Silent (SNP) | VAF 85/393 reads (22%) | called by muse, mutect2, varscan2
- DHX16 | c.550C>A p.R184= | Silent (SNP) | VAF 70/345 reads (20%) | catalogued as COSV64579980; called by muse, mutect2, varscan2
- GALNT17 | c.132G>A p.P44= | Silent (SNP) | VAF 48/151 reads (32%) | catalogued as rs375405409; called by muse, mutect2, varscan2
- MSX1 | c.63C>T p.F21= | Silent (SNP) | VAF 61/157 reads (39%) | called by muse, mutect2, varscan2
- OSM | c.48A>C p.A16= | Silent (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- PSD4 | c.3000G>A p.L1000= | Silent (SNP) | VAF 71/273 reads (26%) | catalogued as rs759050359; called by muse, mutect2, varscan2
- RYR1 | c.12570G>A p.E4190= | Silent (SNP) | VAF 52/141 reads (37%) | called by muse, mutect2, varscan2
- SMPDL3B | c.174C>T p.P58= | Silent (SNP) | VAF 372/718 reads (52%) | called by muse, mutect2, varscan2
- SV2B | c.159C>T p.I53= | Silent (SNP) | VAF 91/279 reads (33%) | catalogued as rs763268034; called by muse, mutect2, varscan2
- UBASH3B | c.831C>A p.P277= | Silent (SNP) | VAF 55/212 reads (26%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2655C>T | 3'UTR (SNP) | VAF 154/617 reads (25%) | catalogued as rs201497655; called by muse, mutect2, varscan2
- DPP6 | c.627+20923G>C | Intron (SNP) | VAF 84/280 reads (30%) | called by muse, mutect2, varscan2
- KCNC3 | chr19:50333997 C>G | 5'Flank (SNP) | VAF 69/217 reads (32%) | called by muse, mutect2, varscan2
- PAPLN | c.-18_-3del | 5'UTR (DEL) | VAF 76/179 reads (42%) | called by mutect2, pindel, varscan2
- TACC2 | c.5834+20231C>T | Intron (SNP) | VAF 54/158 reads (34%) | called by muse, mutect2, varscan2
- WASF4P | n.703A>C | RNA (SNP) | VAF 101/316 reads (32%) | called by muse, mutect2, varscan2
- ZFP36L2 | c.-1C>T | 5'UTR (SNP) | VAF 121/321 reads (38%) | catalogued as rs201662483; called by muse, mutect2, varscan2
